Somatic mutation profile of tumor specimen MP2PRT-PARRCJ-TMP1-A (aliquot MP2PRT-PARRCJ-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARRCJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,663 days).
Specimen MP2PRT-PARRCJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06cb98f3-91d6-412b-a1bc-2a22373b83fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRCJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRCJ-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91287ad2-18a5-4348-bdc2-a16c53f796b5

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Ins 3, Intron 1, Nonsense Mutation 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 346/1020 reads (34%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/266 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 269/444 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV57871006; called by muse, mutect2, varscan2
- AGL | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as rs143987049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPLX1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 377/1296 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs376139437; called by muse, mutect2, varscan2
- CTTNBP2 | c.2258A>T p.K753M | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV50418588; called by muse, mutect2, varscan2
- GPR158 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 50/1164 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66274018; called by muse, mutect2
- KCNH2 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 22/660 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV51211671; called by muse, mutect2
- LRCH3 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs111886622; called by muse, mutect2, varscan2
- LZTR1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 172/431 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs935736801, COSV53151511; called by muse, mutect2, varscan2
- NAT14 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 346/954 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs561771561; called by muse, varscan2
- PAX5 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 277/598 reads (46%) | catalogued as COSV63914939; called by muse, mutect2, varscan2
- PLXNB3 | c.4876C>T p.R1626C | Missense Mutation (SNP) | VAF 32/983 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs782507457; called by muse, mutect2
- PPP1R13B | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 374/1311 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1435913639; called by muse, mutect2, varscan2
- RASGEF1C | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 171/732 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs1410762395, COSV63177819; called by muse, mutect2, varscan2
- RGS3 | c.2729G>A p.R910H (on ENST00000350696 / NM_001282923.2; = p.R629H on NM_130795.4) | Missense Mutation (SNP) | VAF 446/1080 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs199501915, COSV59512627; called by muse, mutect2, varscan2
- ETV6 | c.646_647insC p.E216Afs*28 | Frame Shift Ins (INS) | VAF 365/886 reads (41%) | called by mutect2, pindel*, varscan2
- FBN3 | c.168G>A p.G56= | Splice Region (SNP) | VAF 159/429 reads (37%) | called by muse, mutect2, varscan2
- FBXO33 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 135/424 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCORL | c.4318_4319insTCCC p.N1440Ifs*4 | Frame Shift Ins (INS) | VAF 68/344 reads (20%) | called by mutect2, pindel*, varscan2*
- MED13 | c.6185C>T p.P2062L | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTA1 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 176/702 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHA8 | c.1007dup p.L336Ffs*23 | Frame Shift Ins (INS) | VAF 81/243 reads (33%) | called by mutect2, pindel, varscan2
- SALL3 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 68/2090 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- TMEM47 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 485/1108 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- DISP2 | c.546C>T p.L182= | Silent (SNP) | VAF 245/575 reads (43%) | catalogued as rs752166813; called by muse, mutect2, varscan2
- DPEP1 | c.246C>T p.S82= | Silent (SNP) | VAF 225/502 reads (45%) | catalogued as rs144509890; called by muse, mutect2, varscan2
- ITGA8 | c.261C>A p.I87= | Silent (SNP) | VAF 225/614 reads (37%) | catalogued as COSV100958876; called by muse, mutect2, varscan2
- PAPPA2 | c.1722T>C p.N574= | Silent (SNP) | VAF 256/568 reads (45%) | called by muse, mutect2, varscan2
- PTPN13 | c.5751C>T p.S1917= (on ENST00000411767 / NM_080683.3; = p.S1898= on NM_006264.3) | Silent (SNP) | VAF 69/285 reads (24%) | catalogued as rs200125083, COSV100365047, COSV57403337; called by muse, mutect2, varscan2
- TSC22D4 | c.933C>T p.G311= | Silent (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- MARCHF1 | c.242+596G>T | Intron (SNP) | VAF 76/283 reads (27%) | called by muse, mutect2, varscan2
